Somatic mutation profile of tumor specimen BA2191D (aliquot aq-BA2191D) from BEATAML1.0 case 2504, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute promyelocytic leukaemia, PML-RAR-alpha; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.9 years (20,404 days).
Specimen BA2191D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65654d15-c586-4cdb-88a5-6dc6a50b7dd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2150D (Solid Tissue Normal), aliquot aq-BA2150D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1630eba2-f307-445e-8232-1f730b78c2d9

The open-access MAF lists 22 somatic variants for this specimen: 20 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.4152T>G p.H1384Q | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs773409968; called by muse, varscan2
- DNMT3A | c.938G>A p.W313* | Nonsense Mutation (SNP) | VAF 49/135 reads (36%) | catalogued as rs1204478457, COSV53047885; called by muse, mutect2, varscan2
- FLNB | c.3189C>G p.I1063M | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55895564; called by muse, mutect2, varscan2
- GRAMD2A | c.803C>A p.P268Q | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV59034913; called by muse, mutect2, varscan2
- KRT34 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs143564749; called by muse, mutect2, varscan2
- MARCO | c.1372G>A p.V458I | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59056051; called by muse, mutect2, varscan2
- MORC2 | c.377C>A p.T126N (on ENST00000397641 / NM_001303256.3; = p.T64N on NM_014941.3) | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99309373; called by muse, mutect2, varscan2
- MPO | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1262027089; called by muse, mutect2, varscan2
- MYOM3 | c.4145G>A p.R1382H | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs574626787; called by muse, mutect2, varscan2
- NRXN3 | c.1798C>T p.R600W (on ENST00000557594 / NM_001272020.2; = p.R1024W on NM_004796.6) | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761243980, COSV55321428, COSV55332853; called by muse, mutect2, varscan2
- PRR14L | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 89/231 reads (39%) | catalogued as COSV57886920; called by muse, mutect2, varscan2
- STAB1 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.188); catalogued as rs779596467, COSV58739541; called by muse, mutect2, varscan2
- ACTR3 | c.275T>A p.F92Y | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- ARID1A | c.2845_2846del p.S949Hfs*57 | Frame Shift Del (DEL) | VAF 31/125 reads (25%) | called by mutect2, pindel, varscan2
- ARID2 | c.4142dup p.S1382Ffs*8 | Frame Shift Ins (INS) | VAF 40/178 reads (22%) | called by pindel, varscan2
- KCTD18 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 76/244 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- MLKL | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- P4HA1 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- SAGE1 | c.1421C>A p.A474E | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- UGGT2 | c.3170G>T p.G1057V | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- RBFOX1 | c.771G>A p.P257= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as rs916986800, COSV60959742; ClinVar: likely benign; called by muse, mutect2, varscan2
- QPRT | chr16:29679128 C>T | 5'Flank (SNP) | VAF 36/90 reads (40%) | catalogued as rs775829531; called by muse, varscan2
